Somatic mutation profile of tumor specimen TCGA-HZ-A77O-01A (aliquot TCGA-HZ-A77O-01A-11D-A33T-08) from TCGA case TCGA-HZ-A77O, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 77.8 years (28,434 days).
Specimen TCGA-HZ-A77O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 521c1cc6-1867-45af-bbff-a98abd2ab483.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-A77O-10A (Blood Derived Normal), aliquot TCGA-HZ-A77O-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2e932a8-941b-4d60-8ce9-a89d325420ab

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 47/143 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 29/160 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 61/166 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ATXN10 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 97/391 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as COSV99425892; called by muse, mutect2, varscan2
- DHRS9 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100513299; called by muse, mutect2, varscan2
- DRP2 | c.1813A>G p.K605E | Missense Mutation (SNP) | VAF 215/945 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100871754; called by muse, mutect2, varscan2
- FAM120C | c.3286G>T p.D1096Y | Missense Mutation (SNP) | VAF 266/1187 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.807); catalogued as COSV100069490; called by muse, mutect2, varscan2
- HNRNPR | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 167/513 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs764215177, COSV56421091; called by muse, mutect2, varscan2
- KMT2C | c.3320A>G p.D1107G | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100065055; called by muse, mutect2, varscan2
- MEGF8 | c.5198G>A p.R1733H (on ENST00000251268 / NM_001271938.2; = p.R1666H on NM_001410.3) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.03); catalogued as rs371976691; called by muse, varscan2
- NOP53 | c.1394T>G p.V465G | Missense Mutation (SNP) | VAF 53/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99884046; called by muse, mutect2, varscan2
- OPN1LW | c.740G>C p.R247P | Missense Mutation (SNP) | VAF 42/1916 reads (2%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100885054, COSV64049338; called by muse, mutect2
- PASK | c.1795G>A p.G599S | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV99298481; called by muse, mutect2
- PREX1 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 104/485 reads (21%) | catalogued as COSV100906012; called by muse, mutect2, varscan2
- RTN4R | c.1295G>A p.G432D | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as COSV50383792; called by muse, mutect2, varscan2
- SAMD9 | c.2552T>C p.I851T | Missense Mutation (SNP) | VAF 105/460 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs1161627399, COSV101180110; called by muse, mutect2, varscan2
- SCD5 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 79/379 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs762891080, COSV56726239; called by muse, mutect2, varscan2
- SH3TC1 | c.650C>G p.P217R | Missense Mutation (SNP) | VAF 87/505 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99794292; called by muse, mutect2, varscan2
- TAF5L | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 87/417 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV99272504; called by muse, mutect2, varscan2
- TENM3 | c.6683G>A p.R2228H | Missense Mutation (SNP) | VAF 74/335 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); catalogued as rs201200379, COSV69300412; called by muse, mutect2, varscan2
- TOX2 | c.506G>A p.R169H (on ENST00000358131 / NM_001098798.2; = p.R118H on NM_032883.3) | Missense Mutation (SNP) | VAF 72/285 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as rs199879040, COSV100363216; called by muse, mutect2, varscan2
- ADAMTS4 | c.561C>A p.A187= | Silent (SNP) | VAF 120/537 reads (22%) | catalogued as COSV100917293; called by muse, mutect2, varscan2
- GRM1 | c.534C>T p.F178= | Silent (SNP) | VAF 203/584 reads (35%) | catalogued as rs1376955627, COSV51109245; called by muse, mutect2, varscan2
- LYG1 | c.258C>T p.I86= | Silent (SNP) | VAF 102/417 reads (24%) | catalogued as rs762574941, COSV57915851; called by muse, mutect2, varscan2
- SULT4A1 | c.213C>T p.G71= | Silent (SNP) | VAF 50/347 reads (14%) | catalogued as rs779387006, COSV99970468; called by muse, mutect2, varscan2
- SUSD1 | c.360C>A p.G120= | Silent (SNP) | VAF 449/1390 reads (32%) | catalogued as COSV100813140; called by muse, mutect2, varscan2
- GGNBP1 | n.846+876C>T | Intron (SNP) | VAF 148/413 reads (36%) | called by muse, mutect2, varscan2
- SLC7A2 | c.1195+351T>G | Intron (SNP) | VAF 220/801 reads (27%) | catalogued as COSV99134257; called by muse, mutect2, varscan2
